Gene-level copy-number profile of tumor specimen TCGA-CV-7407-01A from TCGA case TCGA-CV-7407, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.0 years (24,475 days).
Specimen TCGA-CV-7407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b0c29cd4-8d23-41d1-a008-9a639a246e0a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7407-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6426c5f-99cf-47c8-81b3-ab52d04f66b1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 473; copy number 2: 11,172; copy number 3: 24,309; copy number 4: 14,410; copy number 5: 3,742; copy number 6: 2,055; copy number 7: 1,359; copy number 8: 348; copy number 9: 433; copy number 10: 151; copy number 11: 189; copy number 12: 151; copy number 13: 157; copy number 14: 98; copy number 15: 436; copy number 16: 108; copy number 17: 3; copy number 19: 108; copy number 21: 89; copy number 25: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7407-01A-11D-2077-01): tumor purity 0.39, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,644 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:199,752,491–248,919,946, 1,141 genes, copy number 7–10 (broad region; genes not listed).
- chr2:173,811,076–203,961,577, 501 genes, copy number 8–14 (broad region; genes not listed).
- chr3:134,313,576–139,782,699, 93 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr3:141,228,726–144,445,844, 64 genes, copy number 11–15 (broad region; genes not listed).
- chr3:146,909,685–155,745,071, 160 genes, copy number 8–17 (within-gene range 3–17) (broad region; genes not listed).
- chr3:155,760,617–173,141,235, 247 genes, copy number 8–19 (within-gene range 4–19) (broad region; genes not listed).
- chr3:174,302,944–192,917,856, 324 genes, copy number 7–19 (broad region; genes not listed).
- chr3:193,241,128–195,657,927, 71 genes, copy number 8 (broad region; genes not listed).
- chr7:38,273,587–38,322,730, 8 genes, copy number 11: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr8:38,082,122–42,051,994, 88 genes, copy number 8–12 (within-gene range 4–12) (broad region; genes not listed).
- chr9:2,900,320–18,910,950, 187 genes, copy number 7–25 (within-gene range 6–25) (broad region; genes not listed).
- chr9:34,179,005–34,252,523, 1 gene, copy number 8 (within-gene range 4–8): UBAP1.
- chr9:34,223,984–34,524,241, 13 genes, copy number 8: AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1.
- chr10:46,005,088–50,279,720, 108 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:50,325,697–50,341,585, 2 genes, copy number 7: AC069547.2, AC069547.1.
- chr10:50,962,993–53,311,065, 20 genes, copy number 8–12: CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1.
- chr11:79,092,848–81,040,236, 13 genes, copy number 7: AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2.
- chr14:21,918,188–22,509,406, 82 genes, copy number 7–11 (broad region; genes not listed).
- chr19:19,856,975–37,369,365, 521 genes, copy number 7–15 (within-gene range 5–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 473. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
